Somatic mutation profile of tumor specimen 0D9XFE from CCDI case PBBJJT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.4 years (2,719 days).
Specimen 0D9XFE: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 27e734f5-aa18-408d-853a-7472933b7737.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0D9XFF (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/95f5337c-b54b-4bda-8126-6a3995ae688b

The open-access MAF lists 31 somatic variants for this specimen: 20 protein-altering or splice-affecting, 8 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 8, 3'UTR 2, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 386/1067 reads (36%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.659A>C p.Y220S | Missense Mutation (SNP) | VAF 157/272 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCG4 | c.68C>T p.T23M | Missense Mutation (SNP) | VAF 37/431 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.212); catalogued as rs752059482, COSV56641872; called by muse, mutect2
- BAG6 | c.2565del p.L856* (on ENST00000676571; = p.L809* on NM_080702.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 198/623 reads (32%) | catalogued as COSV52993201; called by mutect2, varscan2
- BECN1 | c.490C>T p.R164C | Missense Mutation (SNP) | VAF 184/464 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); catalogued as rs147205679; called by muse, mutect2, varscan2
- BRD9 | c.1243G>A p.D415N | Missense Mutation (SNP) | VAF 252/1349 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763086894, COSV60245243; called by muse, mutect2, varscan2
- CACNA1H | c.2593G>A p.V865M | Missense Mutation (SNP) | VAF 121/429 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1305844490, COSV62001831; called by muse, mutect2, varscan2
- GUCY1B1 | c.77A>G p.K26R | Missense Mutation (SNP) | VAF 192/478 reads (40%) | SIFT tolerated (0.43); PolyPhen benign (0.115); catalogued as rs1240254197; called by muse, mutect2, varscan2
- KIF4A | c.1277C>T p.A426V | Missense Mutation (SNP) | VAF 263/423 reads (62%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs773017445, COSV65541226; called by muse, mutect2, varscan2
- NALCN | c.2081G>A p.R694H | Missense Mutation (SNP) | VAF 318/2006 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.477); catalogued as COSV51932238; called by muse, mutect2
- RAP1GDS1 | c.754G>A p.A252T (on ENST00000408927 / NM_001100427.2; = p.A253T on NM_021159.5) | Missense Mutation (SNP) | VAF 322/947 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.26); catalogued as COSV52791667; called by muse, mutect2, varscan2
- SHISA7 | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs1465803971; called by muse, mutect2, varscan2
- UNC5D | c.554G>T p.G185V | Missense Mutation (SNP) | VAF 358/944 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54847167; called by muse, mutect2, varscan2
- EPPK1 | c.5545G>A p.A1849T | Missense Mutation (SNP) | VAF 163/462 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- FAM160A2 | c.2755C>G p.L919V (on ENST00000449352 / NM_001098794.2; = p.L933V on NM_032127.4) | Missense Mutation (SNP) | VAF 112/233 reads (48%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- FOXP2 | c.755C>T p.P252L | Missense Mutation (SNP) | VAF 401/1224 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- FSD1L | c.1433C>A p.T478K | Missense Mutation (SNP) | VAF 62/1053 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); called by muse, mutect2
- SNTG2 | c.96G>C p.L32F | Missense Mutation (SNP) | VAF 403/1058 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- USP40 | c.316C>T p.L106F | Missense Mutation (SNP) | VAF 59/1696 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- USP51 | c.1847C>T p.P616L | Missense Mutation (SNP) | VAF 129/670 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- ABCA6 | c.1572A>C p.L524= | Silent (SNP) | VAF 114/1400 reads (8%) | called by muse, mutect2
- DENND1B | c.1059C>A p.I353= | Silent (SNP) | VAF 30/1312 reads (2%) | called by muse, mutect2
- LAMA3 | c.4989C>T p.D1663= | Silent (SNP) | VAF 310/795 reads (39%) | catalogued as rs1364907871; called by muse, mutect2, varscan2
- PTCHD3 | c.228C>G p.P76= | Silent (SNP) | VAF 60/674 reads (9%) | catalogued as rs757300294; called by muse, mutect2
- RWDD4 | c.468G>A p.L156= | Silent (SNP) | VAF 384/1169 reads (33%) | called by muse, mutect2, varscan2
- SEZ6L2 | c.1299C>T p.D433= (on ENST00000308713 / NM_001114099.3; = p.D363= on NM_012410.4) | Silent (SNP) | VAF 81/218 reads (37%) | called by muse, mutect2, varscan2
- SHISA7 | c.507G>A p.R169= | Silent (SNP) | VAF 16/128 reads (13%) | called by muse, mutect2, varscan2
- TNS1 | c.4392C>T p.Y1464= | Silent (SNP) | VAF 283/823 reads (34%) | catalogued as rs764441205; called by muse, mutect2, varscan2
- B4GALNT1 | c.*81C>T | 3'UTR (SNP) | VAF 872/1254 reads (70%) | catalogued as COSV100247024; called by muse, mutect2, varscan2
- CSNK2B | c.73-17C>T | Intron (SNP) | VAF 202/711 reads (28%) | called by muse, mutect2, varscan2
- SRSF10 | c.*3311A>C | 3'UTR (SNP) | VAF 140/360 reads (39%) | called by muse, mutect2, varscan2
